Somatic mutation profile of tumor specimen ALCH-AE71-TTR1-A (aliquot ALCH-AE71-TTR1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-AE71, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.0 years (21,926 days).
Specimen ALCH-AE71-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6866b82a-17b2-48d5-9143-992743e69250.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE71-NB1-A (Blood Derived Normal), aliquot ALCH-AE71-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d367211a-ff21-48ce-8d97-f0fb8b872661

The open-access MAF lists 577 somatic variants for this specimen: 397 protein-altering or splice-affecting, 127 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 339, Silent 127, Nonsense Mutation 26, Intron 16, Frame Shift Del 13, 5'UTR 12, Splice Site 10, 3'UTR 8, RNA 7, 3'Flank 6, Splice Region 4, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAN2B1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 278/549 reads (51%) | catalogued as rs370803545, CM124057, COSV54417226; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKP2 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 196/591 reads (33%) | catalogued as rs1565590309; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 219/355 reads (62%) | catalogued as rs786204910, CM110130, CM1513152, COSV64288346; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 664/895 reads (74%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TYR | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as rs797046083; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.758del p.G253Dfs*20 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as COSV52220048; called by pindel, varscan2
- ACAN | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV61359538; called by muse, mutect2, varscan2
- ACSL5 | c.157G>A p.G53R (on ENST00000354273; = p.G109R on NM_016234.3) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV61133355; called by muse, mutect2, varscan2
- ALDH3B1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 149/530 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368554544; called by muse, mutect2, varscan2
- ALMS1 | c.2610C>G p.F870L | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs765797801, COSV100043686; called by muse, mutect2, varscan2
- ANK3 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 97/182 reads (53%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs1168207932, COSV55048591; called by muse, mutect2, varscan2
- AP3D1 | c.3194G>A p.G1065E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61432871; called by muse, mutect2, varscan2
- APOB | c.6098C>T p.P2033L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs942322399; called by muse, mutect2, varscan2
- ASAP2 | c.2566G>A p.V856I | Missense Mutation (SNP) | VAF 112/377 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs771896140; called by muse, mutect2, varscan2
- ATP1A3 | c.2074G>A p.V692I (on ENST00000545399 / NM_001256214.2; = p.V679I on NM_152296.5) | Missense Mutation (SNP) | VAF 305/446 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs781854249; called by muse, mutect2, varscan2
- AUTS2 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 98/198 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV61383273; called by muse, mutect2, varscan2
- BRAF | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV56191665; called by muse, mutect2, varscan2
- C10orf71 | c.3941C>T p.S1314F | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60506613; called by muse, mutect2, varscan2
- CAPRIN2 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as COSV99195771; called by muse, mutect2, varscan2
- CCDC166 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs782582415; called by muse, mutect2
- CCN2 | c.256T>A p.S86T | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as rs755868110; called by muse, mutect2
- CD1C | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 64/413 reads (15%) | catalogued as COSV63806991; called by muse, mutect2, varscan2
- CD8A | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 326/710 reads (46%) | catalogued as COSV99374189; called by muse, mutect2, varscan2
- CDH10 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 151/442 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.757); catalogued as COSV52568861; called by muse, mutect2, varscan2
- CDKN2A | c.150+1G>C p.X50_splice | Splice Site (SNP) | VAF 213/307 reads (69%) | catalogued as COSV58682660, COSV58691878; called by muse, mutect2, varscan2
- CENPB | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.074); catalogued as rs747515195; called by muse, mutect2, varscan2
- CNST | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63619910; called by muse, mutect2, varscan2
- COL5A3 | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs1169675851; called by muse, mutect2, varscan2
- CPN1 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 357/541 reads (66%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs754989179; called by muse, mutect2, varscan2
- CSMD3 | c.1477G>A p.E493K (on ENST00000297405 / NM_001363185.1; = p.E389K on NM_052900.3) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52318007; called by muse, varscan2
- CTNNA2 | c.2141T>C p.L714P | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58183951; called by muse, mutect2, varscan2
- CYBB | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM106243, COSV101059802; called by muse, mutect2
- CYP11B2 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 380/921 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs748286965; called by muse, varscan2
- DACH1 | c.2263A>G p.T755A (on ENST00000619232 / NM_001366712.1; = p.T501A on NM_004392.6) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs769831049; called by muse, mutect2, varscan2
- DLGAP4 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs748210279, COSV100211119; called by muse, mutect2
- DSCAM | c.4382G>C p.R1461P | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68020951; called by muse, mutect2, varscan2
- E2F7 | c.2156A>G p.N719S | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1220655988, COSV59737558; called by mutect2, varscan2
- EAF2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs551917491; called by muse, mutect2, varscan2
- EHD2 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 279/398 reads (70%) | SIFT tolerated (0.8); PolyPhen benign (0.017); catalogued as rs796785999, COSV54408668; called by muse, mutect2, varscan2
- EID1 | c.172A>G p.M58V | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs1390981014; called by muse, mutect2, varscan2
- EML3 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as rs200686766; called by muse, mutect2, varscan2
- ENPP2 | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs1252546525; called by muse, mutect2
- EOLA1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 129/180 reads (72%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs370085115, COSV100828416; called by muse, mutect2, varscan2
- EPB41L3 | c.2632G>A p.G878R | Missense Mutation (SNP) | VAF 199/871 reads (23%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs140662824, COSV59453796; called by muse, mutect2, varscan2
- FAM135B | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99428488; called by muse, mutect2, varscan2
- FAM171A1 | c.1604G>C p.R535T | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV65313968; called by muse, mutect2, varscan2
- FAM47C | c.2245A>T p.S749C | Missense Mutation (SNP) | VAF 215/342 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV63731849; called by muse, mutect2, varscan2
- FAT3 | c.7498A>G p.T2500A | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs939753916; called by muse, mutect2, varscan2
- FMN2 | c.5079G>T p.E1693D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV60431303; called by muse, varscan2
- FMN2 | c.5080G>T p.V1694L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV60418249; called by muse, varscan2
- FPR2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 180/262 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60672165; called by muse, mutect2, varscan2
- FUT5 | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 358/747 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs758420902, COSV53138565; called by muse, mutect2, varscan2
- GALT | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 420/630 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs553769637, COSV66592816; called by muse, mutect2, varscan2
- GLI3 | c.528C>G p.I176M | Missense Mutation (SNP) | VAF 213/598 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as rs539622820; ClinVar: likely benign; called by muse, mutect2, varscan2
- GOLGA3 | c.4154C>G p.P1385R | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs374171027; called by muse, mutect2, varscan2
- GPC5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs372530892, COSV65605013, COSV65615616; called by muse, mutect2, varscan2
- GPR26 | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 182/340 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52933687; called by muse, mutect2, varscan2
- GPR34 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.023); catalogued as rs973745625; called by muse, mutect2
- GRIA4 | c.1850C>G p.S617C | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56882722; called by muse, mutect2
- GRM3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100862178, COSV64469260; called by muse, mutect2, varscan2
- GRM3 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 287/582 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV64466627; called by muse, mutect2, varscan2
- GYS2 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs376308462; called by muse, mutect2, varscan2
- H2BC10 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 181/270 reads (67%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as COSV100010382; called by muse, mutect2, varscan2
- HSPA4 | c.1630del p.A544Qfs*29 | Frame Shift Del (DEL) | VAF 103/210 reads (49%) | catalogued as COSV100507572; called by mutect2, pindel, varscan2
- HSPB8 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.638); catalogued as COSV56137113; called by muse, mutect2
- INTS10 | c.1997G>T p.G666V | Missense Mutation (SNP) | VAF 84/136 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67604844; called by muse, mutect2, varscan2
- KCNN2 | c.1650C>A p.H550Q (on ENST00000264773; = p.H762Q on NM_021614.4) | Missense Mutation (SNP) | VAF 254/407 reads (62%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.672); catalogued as rs573113551, COSV53282271, COSV53287243; called by muse, mutect2, varscan2
- KLKB1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 216/373 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175927695; called by muse, mutect2, varscan2
- LAMA5 | c.8776G>T p.D2926Y | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV53360114; called by muse, mutect2, varscan2
- LBHD1 | c.592C>T p.L198F (on ENST00000431002 / NM_001367940.1; = p.L172F on NM_024099.3) | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs752428625; called by muse, mutect2, varscan2
- LILRB3 | c.1315C>G p.L439V | Missense Mutation (SNP) | VAF 199/289 reads (69%) | SIFT tolerated (0.54); catalogued as rs1305789825; called by mutect2, varscan2
- LRP1B | c.6172G>C p.D2058H | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67208297; called by muse, mutect2, varscan2
- LRP2 | c.5063G>A p.G1688E | Missense Mutation (SNP) | VAF 65/429 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55548888; called by muse, mutect2, varscan2
- LRRTM1 | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV99702258; called by muse, mutect2, varscan2
- MINAR1 | c.1850G>C p.R617P | Missense Mutation (SNP) | VAF 143/349 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100548641; called by muse, mutect2, varscan2
- MKRN3 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as COSV58808622; called by muse, mutect2, varscan2
- MMP16 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54160622; called by muse, mutect2, varscan2
- MRPS22 | c.229A>G p.I77V (on ENST00000310776 / NM_001363893.1; = p.I78V on NM_020191.4) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs200542439; called by muse, mutect2
- MSGN1 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 282/601 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99808771; called by muse, mutect2, varscan2
- MTMR7 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51668392; called by muse, mutect2, varscan2
- MUC16 | c.41441A>T p.K13814M | Missense Mutation (SNP) | VAF 18/449 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV66690226; called by muse, mutect2
- MYO1G | c.2464del p.L822Cfs*36 | Frame Shift Del (DEL) | VAF 211/518 reads (41%) | catalogued as rs757512966; called by mutect2, pindel, varscan2
- MYO3B | c.3367G>A p.A1123T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs201309976; called by muse, mutect2, varscan2
- NACAD | c.3133C>G p.L1045V | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV101512085, COSV71989510; called by muse, mutect2, varscan2
- NOP58 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV51896269; called by muse, mutect2, varscan2
- NOS2 | c.716A>T p.N239I | Missense Mutation (SNP) | VAF 189/443 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766310430; called by muse, mutect2, varscan2
- OR11L1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765282726; called by muse, mutect2, varscan2
- OR2T10 | c.879G>T p.R293S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57898199; called by muse, mutect2
- OR4Q3 | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 126/662 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100056850; called by muse, mutect2, varscan2
- OR5AP2 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57258708; called by muse, mutect2, varscan2
- OR5C1 | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV65456006; called by muse, mutect2, varscan2
- OR5H1 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV63402926; called by muse, mutect2, varscan2
- OR6N1 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748295118; called by muse, mutect2, varscan2
- OR7D2 | c.411C>G p.N137K | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.082); catalogued as COSV100713095; called by muse, mutect2, varscan2
- PCNX2 | c.2477G>C p.R826P | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50833920; called by muse, mutect2, varscan2
- PDE3A | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 44/189 reads (23%) | catalogued as rs1394499677, COSV100761695; called by muse, mutect2, varscan2
- PEX5L | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.931); catalogued as COSV55857508; called by muse, mutect2, varscan2
- PIK3CB | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 102/594 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100006192, COSV56687147; called by muse, mutect2, varscan2
- POLR1A | c.3394C>T p.R1132* | Nonsense Mutation (SNP) | VAF 159/383 reads (42%) | catalogued as COSV99807826; called by muse, mutect2, varscan2
- POTEG | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 276/3607 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs762521548; called by muse, mutect2
- PPP6C | c.353A>T p.Q118L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV65207124; called by muse, mutect2, varscan2
- PRB4 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs547141690, COSV54396160; called by muse, mutect2, varscan2
- PRKAB1 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs755243236; called by muse, mutect2, varscan2
- PRRC2C | c.3461G>T p.R1154L (on ENST00000367742; = p.R1152L on NM_015172.4) | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs767926177, COSV100145314; called by muse, mutect2, varscan2
- PSD | c.2089A>T p.K697* | Nonsense Mutation (SNP) | VAF 134/284 reads (47%) | catalogued as COSV50049543; called by muse, mutect2, varscan2
- PTPRD | c.3190G>A p.D1064N | Missense Mutation (SNP) | VAF 69/108 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1338134782, COSV100647481; called by muse, mutect2, varscan2
- PUM1 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57086073; called by muse, mutect2, varscan2
- PWWP2B | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 131/256 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV59452942; called by muse, mutect2, varscan2
- RAPGEF4 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV51418432; called by muse, mutect2, varscan2
- RSF1 | c.4099G>T p.D1367Y | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs750916857; called by muse, mutect2, varscan2
- RYR1 | c.4879G>A p.V1627M | Missense Mutation (SNP) | VAF 113/1686 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as rs568486136; ClinVar: uncertain significance; called by muse, mutect2
- RYR1 | c.14605G>T p.D4869Y | Missense Mutation (SNP) | VAF 188/3087 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616502; called by muse, mutect2
- SEPHS1 | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV59259417; called by muse, mutect2, varscan2
- SIPA1L3 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.165); catalogued as rs1332502345; called by muse, mutect2, varscan2
- SLC18A3 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 116/382 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60321984; called by muse, mutect2, varscan2
- SORCS1 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs935906514; called by muse, mutect2, varscan2
- SVEP1 | c.1564G>T p.G522W | Missense Mutation (SNP) | VAF 94/416 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57050808; called by muse, mutect2, varscan2
- TACC2 | c.3960G>T p.E1320D | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100551806; called by muse, mutect2
- TECTA | c.4376G>A p.C1459Y | Missense Mutation (SNP) | VAF 128/492 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99881038; called by muse, mutect2, varscan2
- TNS2 | c.3241G>A p.G1081R (on ENST00000314250 / NM_170754.4; = p.G1091R on NM_015319.2) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs752823501; called by muse, mutect2, varscan2
- TPTE | c.1386A>G p.I462M (on ENST00000618007 / NM_199261.4; = p.I444M on NM_199259.4) | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1455136362; called by muse, varscan2
- TRIM48 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV70161564; called by muse, mutect2, varscan2
- TRIM49C | c.87C>A p.D29E | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.95); catalogued as COSV99081627; called by mutect2, varscan2
- TTC3 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV61294713; called by muse, mutect2, varscan2
- TTN | c.33304C>G p.P11102A (on ENST00000591111; = p.P10175A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | PolyPhen benign (0.011); catalogued as COSV59969738; called by muse, mutect2, varscan2
- TTN | c.4078G>A p.G1360R (on ENST00000591111; = p.G1314R on NM_003319.4) | Missense Mutation (SNP) | VAF 32/217 reads (15%) | PolyPhen probably damaging (1); catalogued as COSV60360027, COSV60367462; called by muse, mutect2, varscan2
- UGT1A3 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs767075573; called by muse, mutect2, varscan2
- UNC13A | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1369895005; called by muse, mutect2, varscan2
- WDR49 | c.896C>T p.T299M (on ENST00000308378 / NM_001366158.1; = p.T640M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200695837, COSV57704608; called by muse, mutect2, varscan2
- ZIC1 | c.980C>G p.T327R | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51554975; called by muse, mutect2, varscan2
- ZNF423 | c.1366del p.D456Tfs*24 (on ENST00000563137 / NM_001379286.1; = p.D448Tfs*24 on NM_015069.4) | Frame Shift Del (DEL) | VAF 141/385 reads (37%) | catalogued as COSV52189855; called by mutect2, pindel, varscan2
- ZNF493 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs765851359, COSV62749251; called by muse, mutect2, varscan2
- AC011005.1 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 150/1009 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ACAN | c.5555C>T p.S1852F | Missense Mutation (SNP) | VAF 20/660 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACIN1 | c.2282G>A p.R761K | Missense Mutation (SNP) | VAF 159/405 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACOX1 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 177/448 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS12 | c.3104C>A p.P1035H | Missense Mutation (SNP) | VAF 112/319 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ADAMTS18 | c.3255G>T p.Q1085H | Missense Mutation (SNP) | VAF 110/538 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS18 | c.2198C>G p.A733G | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ADAMTS20 | c.2427T>A p.N809K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY3 | c.2713C>G p.L905V | Missense Mutation (SNP) | VAF 129/287 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- ADGRA2 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRB3 | c.3415C>A p.Q1139K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.266); called by muse, varscan2
- ADGRV1 | c.8174A>G p.H2725R | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.2); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- AGFG1 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, varscan2
- ALG2 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALK | c.1895T>G p.L632R | Missense Mutation (SNP) | VAF 175/479 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- AMOTL1 | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- AMOTL1 | c.1952G>T p.G651V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ANAPC5 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.181); called by muse, mutect2
- ANKRD13B | c.1096C>A p.Q366K | Missense Mutation (SNP) | VAF 74/138 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ANKRD18B | c.1990A>T p.T664S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.301); called by muse, mutect2
- ANKRD36C | c.1933G>T p.G645W | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- APOB | c.7756dup p.T2586Nfs*4 | Frame Shift Ins (INS) | VAF 82/337 reads (24%) | called by mutect2, pindel, varscan2
- ARID1B | c.1419G>T p.M473I | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARL3 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ARPC2 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ARPP21 | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARX | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 133/179 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ASB2 | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ASTN1 | c.1991G>T p.C664F | Missense Mutation (SNP) | VAF 363/639 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP13A1 | c.350C>G p.S117W | Missense Mutation (SNP) | VAF 161/293 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- ATP8B2 | c.1773_1776del p.Y591* (on ENST00000672630; = p.Y558* on NM_001367934.1 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 59/391 reads (15%) | called by mutect2, pindel*, varscan2*
- BCKDK | c.375+2T>C p.X125_splice | Splice Site (SNP) | VAF 205/394 reads (52%) | called by muse, mutect2, varscan2
- BPTF | c.7995+1G>T p.X2665_splice | Splice Site (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- C1orf162 | c.78C>G p.S26R | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- C3 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- C4orf54 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- C7 | c.1569C>A p.C523* | Nonsense Mutation (SNP) | VAF 55/180 reads (31%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.1154A>G p.Q385R | Missense Mutation (SNP) | VAF 192/351 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CAPRIN1 | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 143/350 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CARD6 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC151 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCL14 | c.158A>C p.Y53S (on ENST00000618404 / NM_032963.4; = p.Y69S on NM_032962.4) | Missense Mutation (SNP) | VAF 134/370 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CD1C | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD1E | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CDSN | c.352T>A p.S118T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CEP85L | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CFAP54 | c.1127A>T p.K376M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CFAP65 | c.4783C>A p.P1595T | Missense Mutation (SNP) | VAF 92/200 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFHR1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CHAT | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 67/91 reads (74%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD4 | c.661A>T p.S221C | Missense Mutation (SNP) | VAF 152/940 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CHERP | c.1135A>T p.S379C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.053); called by mutect2, varscan2
- CHPF | c.1928A>G p.H643R | Missense Mutation (SNP) | VAF 181/413 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLEC4M | c.1171A>T p.K391* | Nonsense Mutation (SNP) | VAF 45/184 reads (24%) | called by muse, mutect2, varscan2
- CLNK | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CMKLR1 | c.674T>A p.F225Y (on ENST00000312143 / NM_001142344.2; = p.F223Y on NM_004072.3) | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CNTN5 | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 70/653 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); called by muse, mutect2
- CNTNAP4 | c.2677G>T p.D893Y | Missense Mutation (SNP) | VAF 269/597 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- COL11A1 | c.4143G>A p.G1381= | Splice Region (SNP) | VAF 277/450 reads (62%) | called by muse, mutect2, varscan2
- COL4A3 | c.2674G>A p.G892R | Missense Mutation (SNP) | VAF 172/385 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A3 | c.4262G>T p.G1421V | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A1 | c.893A>T p.K298M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- COPB1 | c.31T>G p.L11V | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CORO1C | c.448+4G>A | Splice Region (SNP) | VAF 13/228 reads (6%) | called by muse, mutect2
- COX15 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 198/313 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CPN2 | c.580A>T p.S194C | Missense Mutation (SNP) | VAF 135/631 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CPT1C | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTNND1 | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 97/400 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DDX25 | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEUP1 | c.1330A>G p.M444V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, varscan2
- DHRS3 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- DHRS7C | c.936del p.*313Nfs*? (on ENST00000330255 / NM_001220493.2; = p.*312Nfs*? on NM_001105571.3) | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- DISP1 | c.3281G>A p.G1094E | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.9889A>G p.I3297V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNER | c.1907G>T p.R636L | Missense Mutation (SNP) | VAF 221/418 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNER | c.690A>T p.Q230H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.556); called by mutect2, varscan2
- DRC1 | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 135/346 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSC3 | c.2311A>T p.M771L | Missense Mutation (SNP) | VAF 94/538 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYRK4 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 158/458 reads (34%) | called by muse, mutect2, varscan2
- ECHDC2 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 134/222 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EFR3A | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ELOVL7 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ESX1 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EXOC1L | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- FAM189A1 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FANCL | c.816T>A p.H272Q | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); called by muse, varscan2
- FBF1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBH1 | c.282C>G p.I94M (on ENST00000362091 / NM_178150.3; = p.I145M on NM_032807.4) | Missense Mutation (SNP) | VAF 77/332 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBRS | c.1026_1027delinsT p.R343Gfs*42 (on ENST00000287468; = p.R863Gfs*42 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 109/722 reads (15%) | called by pindel, varscan2*
- FCRL2 | c.1235C>A p.T412N | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- FCRL5 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCSK | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- FERMT3 | c.603_604del p.Q202Afs*71 | Frame Shift Del (DEL) | VAF 230/484 reads (48%) | called by mutect2, pindel, varscan2
- FIG4 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.2249G>C p.S750T | Missense Mutation (SNP) | VAF 535/993 reads (54%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FLRT3 | c.842dup p.N281Kfs*2 | Frame Shift Ins (INS) | VAF 30/160 reads (19%) | called by mutect2, pindel, varscan2
- FNDC4 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 132/317 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXL2 | c.657G>C p.Q219H | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FPR3 | c.438G>C p.M146I | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSHR | c.1789C>T p.L597F | Missense Mutation (SNP) | VAF 134/273 reads (49%) | SIFT tolerated (0.73); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- FUT9 | c.342T>A p.S114R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- GAB2 | c.121G>T p.G41C (on ENST00000361507 / NM_080491.3; = p.G3C on NM_012296.3) | Missense Mutation (SNP) | VAF 108/216 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAGE10 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 30/886 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- GAP43 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 164/261 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- GFI1B | c.941A>T p.Q314L | Missense Mutation (SNP) | VAF 479/880 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLT1D1 | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLUD2 | c.1672A>C p.T558P | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- GLYR1 | c.538-1G>A p.X180_splice | Splice Site (SNP) | VAF 11/342 reads (3%) | called by muse, mutect2
- GPR31 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 161/382 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- GRIA4 | c.1158G>A p.K386= | Splice Region (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- GRIN2B | c.2361G>A p.G787= | Splice Region (SNP) | VAF 96/323 reads (30%) | called by muse, mutect2, varscan2
- HDGFL2 | c.1242G>C p.K414N | Missense Mutation (SNP) | VAF 167/332 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- HOXD3 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- HPS6 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 98/1136 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- HSPH1 | c.2184G>C p.K728N | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- IGFN1 | c.2164G>T p.V722L (on ENST00000295591 / NM_001367841.1; = p.V3179L on NM_001164586.2) | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- IGSF10 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- IL10RA | c.524C>A p.P175Q | Missense Mutation (SNP) | VAF 113/528 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IL1RAP | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 102/178 reads (57%) | called by muse, mutect2, varscan2
- ITGAD | c.3011A>G p.D1004G | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- ITGAM | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITIH4 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 140/215 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IVL | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 83/442 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- KAT2B | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KAT6A | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.351); called by muse, mutect2
- KCNJ3 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KCNK18 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 156/291 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- KHDC1L | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- KRTAP5-2 | c.283A>T p.K95* | Nonsense Mutation (SNP) | VAF 134/257 reads (52%) | called by muse, mutect2, varscan2
- LAMA2 | c.893T>A p.L298H | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIG4 | c.2405G>C p.R802P | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- LRP1 | c.10951G>C p.V3651L | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LRP1B | c.5209+1G>T p.X1737_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- LRP1B | c.3767-1G>T p.X1256_splice | Splice Site (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- LRRC14B | c.381G>T p.R127S | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC7 | c.1016T>G p.L339* (on ENST00000651989 / NM_001370785.2; = p.L306* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/36 reads (72%) | called by muse, varscan2
- LRRK2 | c.1537del p.V513Cfs*18 | Frame Shift Del (DEL) | VAF 22/150 reads (15%) | called by mutect2, pindel, varscan2
- MAGEB16 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MAP3K3 | c.1484T>G p.I495S | Missense Mutation (SNP) | VAF 75/425 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAPT | c.1118C>A p.P373H (on ENST00000262410 / NM_001377265.1; = p.P298H on NM_016835.4) | Missense Mutation (SNP) | VAF 133/424 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MARS1 | c.956A>T p.E319V | Missense Mutation (SNP) | VAF 122/584 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MC5R | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 268/619 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MCTP1 | c.1843C>G p.P615A | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MEPE | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MIB1 | c.2183A>T p.D728V | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- MILR1 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- MORC1 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MRM2 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 149/466 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- MTRR | c.736G>T p.V246F (on ENST00000264668; = p.V219F on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MUC13 | c.1268T>A p.L423H | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.40469T>A p.L13490Q | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC16 | c.10046G>C p.G3349A | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MUC21 | c.1601A>G p.H534R | Missense Mutation (SNP) | VAF 234/369 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MUC5AC | c.474_475del p.X158_splice | Splice Site (DEL) | VAF 54/267 reads (20%) | called by mutect2, pindel, varscan2
- MYH8 | c.2830A>T p.R944* | Nonsense Mutation (SNP) | VAF 324/480 reads (68%) | called by muse, mutect2, varscan2
- MYOM1 | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); called by muse, mutect2
- NAALADL2 | c.1719A>G p.I573M | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, varscan2
- NBEA | c.5522G>T p.G1841V | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NIPBL | c.5269G>A p.V1757I | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.791); called by muse, mutect2
- NLRP3 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 74/439 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- NMBR | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NNT | c.2767G>C p.E923Q | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- NRAP | c.4483C>T p.P1495S (on ENST00000359988 / NM_001322945.2; = p.P1460S on NM_006175.4) | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NRP1 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- NUTM2A | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by mutect2, varscan2
- NWD2 | c.3884G>C p.S1295T | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- OBSCN | c.4093G>A p.G1365R | Missense Mutation (SNP) | VAF 93/466 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OPRK1 | c.1035C>A p.C345* | Nonsense Mutation (SNP) | VAF 136/478 reads (28%) | called by muse, mutect2, varscan2
- OR2G6 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- OR2L5 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 167/360 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR2T10 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- OR4A15 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4C46 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- OR51V1 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5F1 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR6C2 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR8G5 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); called by muse, varscan2
- OTOGL | c.4499C>T p.S1500F (on ENST00000547103; = p.S1491F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PANK3 | c.201C>A p.H67Q | Missense Mutation (SNP) | VAF 162/250 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PAPPA | c.3881A>T p.Y1294F | Missense Mutation (SNP) | VAF 55/563 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PARP14 | c.834A>T p.K278N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by mutect2, varscan2
- PAX1 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 265/995 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCK1 | c.570_599del p.K191_L200del | In Frame Del (DEL) | VAF 48/162 reads (30%) | called by mutect2, pindel
- PEDS1-UBE2V1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PIGR | c.1207G>T p.G403W | Missense Mutation (SNP) | VAF 289/468 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3C2B | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PLCB3 | c.1174G>T p.V392L | Missense Mutation (SNP) | VAF 279/560 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- PLPPR4 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POU6F2 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 162/590 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPL | c.162+1G>C p.X54_splice | Splice Site (SNP) | VAF 172/343 reads (50%) | called by muse, mutect2, varscan2
- PPP1R21 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.426); called by muse, mutect2
- PPP4R1 | c.2057_2073delinsT p.S686Lfs*8 (on ENST00000400556 / NM_001042388.3; = p.S669Lfs*8 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | called by pindel, varscan2*
- PPP4R3C | c.122T>A p.L41H | Missense Mutation (SNP) | VAF 122/186 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PPP6R3 | c.2039-2A>T p.X680_splice (on ENST00000393800 / NM_001352375.2; = p.X600_splice on NM_018312.5) | Splice Site (SNP) | VAF 70/316 reads (22%) | called by muse, mutect2, varscan2
- PRKCQ | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRNP | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 170/661 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRRC2A | c.3606G>T p.L1202F | Missense Mutation (SNP) | VAF 101/177 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PSTK | c.944T>C p.I315T | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCH1 | c.1205C>A p.T402K | Missense Mutation (SNP) | VAF 66/646 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRQ | c.5419A>T p.T1807S (on ENST00000616559; = p.T1765S on NM_001145026.2) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- QSER1 | c.184C>T p.Q62* (on ENST00000399302; = p.Q191* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 57/143 reads (40%) | called by muse, mutect2, varscan2
- QSER1 | c.577C>T p.Q193* (on ENST00000399302; = p.Q322* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 55/124 reads (44%) | called by muse, mutect2, varscan2
- RAD23A | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 60/244 reads (25%) | called by muse, mutect2, varscan2
- RGS22 | c.906T>A p.D302E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- RICTOR | c.4985A>T p.H1662L | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIOK3 | c.338_341del p.F113* | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- RNF148 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RNF213 | c.6282G>C p.L2094F | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RPRD1B | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 350/664 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR1 | c.7945G>C p.E2649Q | Missense Mutation (SNP) | VAF 96/1849 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- RYR1 | c.8524A>G p.I2842V | Missense Mutation (SNP) | VAF 54/1023 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.058); called by muse, mutect2
- RYR2 | c.1949A>G p.N650S | Missense Mutation (SNP) | VAF 129/243 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SAMHD1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 211/468 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN1A | c.4220G>A p.R1407Q (on ENST00000303395 / NM_001202435.3; = p.R1396Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SDK1 | c.3862G>T p.V1288F | Missense Mutation (SNP) | VAF 206/483 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SEC16B | c.1401G>A p.W467* | Nonsense Mutation (SNP) | VAF 54/344 reads (16%) | called by muse, mutect2, varscan2
- SERPINB9 | c.212A>T p.Q71L | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SERPINI1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 78/512 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SFSWAP | c.2351C>G p.S784* | Nonsense Mutation (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- SGIP1 | c.67del p.D23Ifs*114 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- SGIP1 | c.1203A>T p.K401N | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SHISA3 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 123/195 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIX5 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 111/151 reads (74%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SLC24A4 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SLC6A5 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMYD1 | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SMYD1 | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SNUPN | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SORCS1 | c.1117G>C p.V373L | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SPATA31A6 | c.3409G>T p.D1137Y | Missense Mutation (SNP) | VAF 129/327 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SPRTN | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- SRCAP | c.3685G>A p.G1229R | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SULF1 | c.23dup p.V9Gfs*44 | Frame Shift Ins (INS) | VAF 109/309 reads (35%) | called by mutect2, pindel, varscan2
- SYNDIG1 | c.517T>G p.F173V | Missense Mutation (SNP) | VAF 90/433 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE4 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 90/491 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- SYTL5 | c.1456C>A p.L486M | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D20 | c.745A>C p.M249L | Missense Mutation (SNP) | VAF 155/377 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TBC1D30 | c.968G>T p.R323L (on ENST00000542120; = p.R160L on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/387 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBXT | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGM6 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 203/471 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TMC2 | c.1053C>G p.Y351* | Nonsense Mutation (SNP) | VAF 69/130 reads (53%) | called by muse, mutect2, varscan2
- TMC2 | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TMEM179 | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 192/238 reads (81%) | SIFT tolerated (0.34); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- TNN | c.2362A>C p.K788Q | Missense Mutation (SNP) | VAF 92/640 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRIM67 | c.1633G>T p.D545Y | Missense Mutation (SNP) | VAF 87/510 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TRIM8 | c.96C>G p.H32Q | Missense Mutation (SNP) | VAF 616/1414 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TUBGCP2 | c.1931A>G p.H644R | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- UBA1 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 116/171 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- UNC80 | c.8126G>T p.G2709V | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.7425dup p.G2476Wfs*21 | Frame Shift Ins (INS) | VAF 306/684 reads (45%) | called by mutect2, pindel, varscan2
- USP32 | c.4552del p.H1518Ifs*52 | Frame Shift Del (DEL) | VAF 57/172 reads (33%) | called by mutect2, pindel, varscan2
- VIP | c.460A>T p.K154* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- VPS13B | c.10886G>T p.R3629M | Missense Mutation (SNP) | VAF 212/548 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS35 | c.719A>T p.Q240L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- WDFY2 | c.485A>T p.Q162L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- WDR17 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR72 | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WRAP53 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 174/454 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- YWHAG | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 54/823 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.301); called by muse, mutect2
- ZDHHC20 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ZFAT | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZIC4 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 509/1660 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF195 | c.1856C>T p.S619L (on ENST00000399602 / NM_001130520.3; = p.S547L on NM_007152.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF679 | c.40-1G>A p.X14_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- ZNF843 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ACVR1 | c.528A>T p.G176= | Silent (SNP) | VAF 90/444 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.4683C>A p.P1561= | Silent (SNP) | VAF 232/642 reads (36%) | called by muse, mutect2, varscan2
- ADRB3 | c.180G>A p.V60= | Silent (SNP) | VAF 892/1455 reads (61%) | called by muse, mutect2, varscan2
- ALG2 | c.501A>T p.T167= | Silent (SNP) | VAF 35/275 reads (13%) | called by muse, mutect2, varscan2
- APOB | c.2052A>T p.S684= | Silent (SNP) | VAF 105/340 reads (31%) | called by muse, mutect2, varscan2
- AQP12B | c.324G>T p.L108= (on ENST00000621682; = p.L120= on NM_001102467.2) | Silent (SNP) | VAF 76/354 reads (21%) | called by muse, mutect2, varscan2
- ATOH8 | c.234C>A p.V78= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs767213610; called by muse, mutect2, varscan2
- BHLHE22 | c.585C>T p.V195= | Silent (SNP) | VAF 106/263 reads (40%) | called by muse, varscan2
- C11orf52 | c.366G>A p.L122= | Silent (SNP) | VAF 8/183 reads (4%) | catalogued as rs1212199395; called by muse, mutect2
- C1S | c.1470C>T p.T490= | Silent (SNP) | VAF 260/706 reads (37%) | catalogued as rs1455806277; called by muse, mutect2, varscan2
- C3 | c.1965C>T p.A655= | Silent (SNP) | VAF 25/786 reads (3%) | called by muse, mutect2
- CACNA1H | c.883C>A p.R295= | Silent (SNP) | VAF 154/344 reads (45%) | called by muse, mutect2, varscan2
- CAPN12 | c.87C>T p.G29= | Silent (SNP) | VAF 347/3164 reads (11%) | catalogued as rs772406674; called by muse, mutect2, varscan2
- CCDC151 | c.1371G>T p.R457= | Silent (SNP) | VAF 48/260 reads (18%) | called by muse, mutect2, varscan2
- CCDC178 | c.244C>A p.R82= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100285401; called by muse, mutect2, varscan2
- CEACAM8 | c.339C>A p.T113= | Silent (SNP) | VAF 48/72 reads (67%) | called by muse, mutect2, varscan2
- CHFR | c.1449C>G p.A483= (on ENST00000432561 / NM_001161345.1; = p.A442= on NM_018223.2) | Silent (SNP) | VAF 160/249 reads (64%) | called by muse, mutect2, varscan2
- CHST2 | c.1083G>A p.P361= | Silent (SNP) | VAF 90/136 reads (66%) | catalogued as rs1437216641; called by muse, mutect2, varscan2
- CLCA1 | c.69A>T p.S23= | Silent (SNP) | VAF 49/82 reads (60%) | called by muse, mutect2, varscan2
- CLCN7 | c.1926G>A p.E642= | Silent (SNP) | VAF 170/678 reads (25%) | catalogued as rs1428861859; called by muse, mutect2, varscan2
- CRAMP1 | c.1941G>T p.A647= | Silent (SNP) | VAF 52/186 reads (28%) | called by muse, mutect2, varscan2
- CTBP1 | c.786G>T p.V262= | Silent (SNP) | VAF 177/276 reads (64%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2142G>T p.L714= | Silent (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- CTNND2 | c.2742T>C p.T914= | Silent (SNP) | VAF 129/405 reads (32%) | called by muse, mutect2, varscan2
- CYFIP2 | c.2670G>T p.R890= (on ENST00000616178 / NM_001291722.2; = p.R865= on NM_014376.4) | Silent (SNP) | VAF 163/282 reads (58%) | catalogued as COSV56637850; called by muse, mutect2, varscan2
- DNAH2 | c.9669C>T p.A3223= | Silent (SNP) | VAF 388/519 reads (75%) | called by muse, mutect2, varscan2
- DNER | c.1908G>C p.R636= | Silent (SNP) | VAF 224/421 reads (53%) | catalogued as COSV104421097, COSV59168180; called by muse, mutect2, varscan2
- DOT1L | c.3897C>T p.S1299= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- DPP8 | c.297C>T p.I99= (on ENST00000341861 / NM_001320875.2; = p.I83= on NM_017743.6) | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.4801C>T p.L1601= | Silent (SNP) | VAF 138/189 reads (73%) | catalogued as rs781283405; called by muse, mutect2, varscan2
- EIF3K | c.609G>A p.E203= | Silent (SNP) | VAF 81/1120 reads (7%) | catalogued as rs377673715; called by muse, mutect2
- EPB41L3 | c.2385C>T p.G795= | Silent (SNP) | VAF 118/362 reads (33%) | called by muse, mutect2, varscan2
- ESRRG | c.1035A>G p.L345= | Silent (SNP) | VAF 182/321 reads (57%) | catalogued as rs750386809; called by muse, mutect2, varscan2
- FAT3 | c.7458A>G p.V2486= | Silent (SNP) | VAF 78/159 reads (49%) | called by muse, mutect2, varscan2
- FCN1 | c.123G>C p.L41= | Silent (SNP) | VAF 93/786 reads (12%) | called by muse, mutect2, varscan2
- FGF3 | c.31C>T p.L11= | Silent (SNP) | VAF 263/558 reads (47%) | called by muse, varscan2
- FHDC1 | c.762G>C p.R254= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- FNIP1 | c.480C>T p.S160= | Silent (SNP) | VAF 57/106 reads (54%) | called by muse, mutect2, varscan2
- FRG2C | c.789T>A p.P263= | Silent (SNP) | VAF 72/924 reads (8%) | called by muse, mutect2
- FUS | c.324C>T p.S108= | Silent (SNP) | VAF 60/325 reads (18%) | called by muse, mutect2, varscan2
- GABRA2 | c.513G>A p.E171= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- GABRG2 | c.1137A>T p.V379= (on ENST00000361925 / NM_001375343.1; = p.V339= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 263/447 reads (59%) | catalogued as rs753372205; called by muse, mutect2, varscan2
- GATA3 | c.378C>G p.S126= | Silent (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- GDF10 | c.1011C>T p.R337= | Silent (SNP) | VAF 85/226 reads (38%) | catalogued as rs1339545709; called by muse, mutect2, varscan2
- GSTZ1 | c.315C>T p.L105= | Silent (SNP) | VAF 159/244 reads (65%) | catalogued as rs776267169; called by muse, mutect2, varscan2
- GTF2H3 | c.495G>A p.K165= | Silent (SNP) | VAF 51/121 reads (42%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.1713C>T p.I571= | Silent (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- HR | c.3543C>T p.A1181= | Silent (SNP) | VAF 140/416 reads (34%) | catalogued as rs372917956; called by muse, mutect2, varscan2
- HRAS | c.282C>T p.H94= | Silent (SNP) | VAF 174/606 reads (29%) | catalogued as rs375893752; ClinVar: likely benign; called by muse, mutect2, varscan2
- IKBKE | c.606G>T p.V202= | Silent (SNP) | VAF 270/481 reads (56%) | called by muse, mutect2, varscan2
- IPO13 | c.2643C>G p.L881= | Silent (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- KANSL1 | c.975G>A p.L325= | Silent (SNP) | VAF 56/653 reads (9%) | called by muse, mutect2
- KCNK3 | c.873G>T p.A291= | Silent (SNP) | VAF 92/229 reads (40%) | catalogued as COSV57191789; called by muse, mutect2, varscan2
- KCNS3 | c.624G>A p.S208= | Silent (SNP) | VAF 54/416 reads (13%) | catalogued as rs140824188; called by muse, mutect2, varscan2
- KIAA0930 | c.282A>T p.G94= (on ENST00000336156 / NM_001009880.2; = p.G99= on NM_015264.2) | Silent (SNP) | VAF 113/514 reads (22%) | called by muse, mutect2, varscan2
- KPNA7 | c.423C>A p.I141= | Silent (SNP) | VAF 271/930 reads (29%) | catalogued as COSV59396949; called by muse, mutect2, varscan2
- LCN6 | c.315G>A p.L105= | Silent (SNP) | VAF 79/591 reads (13%) | catalogued as rs1302757244; called by muse, mutect2, varscan2
- LINGO1 | c.1275C>T p.R425= | Silent (SNP) | VAF 117/580 reads (20%) | catalogued as rs1470892677; called by muse, mutect2, varscan2
- LRIF1 | c.1212C>T p.V404= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1201436591; called by muse, mutect2, varscan2
- MAGEA1 | c.474C>T p.D158= | Silent (SNP) | VAF 76/111 reads (68%) | catalogued as rs782245100, COSV63119140; called by muse, mutect2, varscan2
- MAGEB1 | c.282C>A p.S94= | Silent (SNP) | VAF 69/112 reads (62%) | catalogued as COSV66775644; called by muse, mutect2, varscan2
- MAGEB4 | c.597G>C p.G199= | Silent (SNP) | VAF 73/123 reads (59%) | called by muse, mutect2, varscan2
- MARCHF8 | c.282C>A p.I94= | Silent (SNP) | VAF 99/216 reads (46%) | catalogued as COSV60575375; called by muse, mutect2, varscan2
- MBTPS1 | c.1197G>T p.R399= | Silent (SNP) | VAF 174/543 reads (32%) | called by muse, mutect2, varscan2
- MMEL1 | c.1035C>A p.G345= | Silent (SNP) | VAF 128/188 reads (68%) | called by muse, mutect2, varscan2
- MORC1 | c.675T>C p.A225= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs1289411403; called by muse, mutect2, varscan2
- MROH9 | c.1551T>A p.P517= | Silent (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- MSANTD3 | c.519A>T p.S173= | Silent (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2, varscan2
- MYO1E | c.2607A>T p.L869= | Silent (SNP) | VAF 115/296 reads (39%) | called by muse, mutect2, varscan2
- NBEA | c.6285G>T p.L2095= | Silent (SNP) | VAF 75/208 reads (36%) | called by muse, mutect2, varscan2
- NBPF9 | c.2781G>T p.V927= | Silent (SNP) | VAF 54/410 reads (13%) | catalogued as rs782465063; called by muse, mutect2, varscan2
- NDST4 | c.2370T>A p.P790= | Silent (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- NIBAN3 | c.1764G>A p.L588= | Silent (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- NLGN4X | c.1152G>A p.V384= | Silent (SNP) | VAF 76/183 reads (42%) | called by muse, mutect2, varscan2
- NLRP12 | c.558C>T p.T186= | Silent (SNP) | VAF 54/94 reads (57%) | catalogued as rs750215766, COSV100146046; called by muse, mutect2, varscan2
- NR4A1 | c.864G>A p.K288= | Silent (SNP) | VAF 106/472 reads (22%) | called by muse, mutect2, varscan2
- NRK | c.4245G>T p.L1415= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV99687835; called by muse, mutect2, varscan2
- NUP188 | c.822G>T p.V274= | Silent (SNP) | VAF 58/159 reads (36%) | catalogued as rs1288739667; called by muse, mutect2, varscan2
- NXNL2 | c.219C>T p.D73= | Silent (SNP) | VAF 176/368 reads (48%) | catalogued as rs1331267528; called by muse, mutect2, varscan2
- OBI1 | c.1698G>T p.G566= | Silent (SNP) | VAF 31/145 reads (21%) | called by muse, mutect2, varscan2
- OR14K1 | c.414C>G p.L138= | Silent (SNP) | VAF 59/257 reads (23%) | catalogued as COSV51721654, COSV99315423; called by muse, mutect2, varscan2
- OR4C13 | c.369C>A p.A123= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV73648673, COSV73648980; called by muse, mutect2, varscan2
- OR5C1 | c.804C>A p.S268= | Silent (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- OR6Q1 | c.822C>T p.F274= | Silent (SNP) | VAF 37/293 reads (13%) | called by muse, mutect2, varscan2
- OR9Q1 | c.507T>C p.C169= | Silent (SNP) | VAF 94/209 reads (45%) | called by muse, mutect2, varscan2
- PAICS | c.930G>C p.L310= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- PCDHB4 | c.72G>A p.Q24= | Silent (SNP) | VAF 98/145 reads (68%) | catalogued as COSV99522530; called by muse, mutect2, varscan2
- PLEKHG4 | c.2790G>A p.Q930= | Silent (SNP) | VAF 212/463 reads (46%) | catalogued as COSV100430752; called by muse, mutect2, varscan2
- PNMA8B | c.1665C>T p.S555= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100885367; called by muse, mutect2
- POU2AF1 | c.327G>T p.V109= | Silent (SNP) | VAF 127/248 reads (51%) | called by muse, mutect2, varscan2
- PRDM10 | c.1635G>A p.L545= | Silent (SNP) | VAF 73/521 reads (14%) | catalogued as rs758693823; called by muse, mutect2, varscan2
- PRKAG3 | c.987G>A p.K329= | Silent (SNP) | VAF 108/570 reads (19%) | called by muse, mutect2, varscan2
- PTGER2 | c.567C>A p.I189= | Silent (SNP) | VAF 181/267 reads (68%) | catalogued as COSV55418519; called by muse, mutect2, varscan2
- PTPN9 | c.240G>C p.L80= | Silent (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- RALY | c.204C>G p.A68= | Silent (SNP) | VAF 145/506 reads (29%) | called by muse, mutect2, varscan2
- RASGEF1C | c.978C>T p.F326= | Silent (SNP) | VAF 42/221 reads (19%) | catalogued as COSV63182667; called by muse, mutect2, varscan2
- RBM19 | c.1038G>A p.V346= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs745486513; called by muse, mutect2, varscan2
- RETSAT | c.1683C>T p.L561= | Silent (SNP) | VAF 55/249 reads (22%) | called by muse, varscan2
- RFX6 | c.1347C>T p.F449= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs751839843, COSV100263115; called by muse, mutect2, varscan2
- RSAD2 | c.168A>T p.P56= | Silent (SNP) | VAF 280/777 reads (36%) | called by muse, mutect2, varscan2
- RYR2 | c.12435C>T p.I4145= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as rs954641240, COSV63671059, COSV63678927; called by muse, mutect2, varscan2
- SENP3 | c.846G>A p.Q282= | Silent (SNP) | VAF 16/418 reads (4%) | catalogued as rs1237232918; called by muse, mutect2
- SLC20A1 | c.1536T>C p.S512= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs755575986; called by muse, mutect2, varscan2
- SLC35G5 | c.207G>T p.S69= | Silent (SNP) | VAF 292/478 reads (61%) | catalogued as COSV55314271; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1890A>G p.A630= (on ENST00000540229 / NM_001371097.1; = p.A569= on NM_001009562.4) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs1448894758; called by muse, mutect2, varscan2
- SMARCA4 | c.1314C>T p.A438= | Silent (SNP) | VAF 67/620 reads (11%) | called by muse, mutect2, varscan2
- SMARCC1 | c.3135G>A p.G1045= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs1464102676; called by muse, mutect2
- SRMS | c.225G>A p.G75= | Silent (SNP) | VAF 95/230 reads (41%) | called by muse, mutect2, varscan2
- SVEP1 | c.6807G>T p.P2269= | Silent (SNP) | VAF 115/392 reads (29%) | catalogued as rs373455337; called by muse, mutect2, varscan2
- TAB1 | c.9G>T p.A3= | Silent (SNP) | VAF 91/586 reads (16%) | called by muse, mutect2, varscan2
- TBC1D24 | c.654G>A p.G218= | Silent (SNP) | VAF 77/414 reads (19%) | called by muse, mutect2, varscan2
- TEP1 | c.6498G>T p.R2166= | Silent (SNP) | VAF 101/296 reads (34%) | called by muse, mutect2, varscan2
- TMEM191B | c.783C>T p.A261= | Silent (SNP) | VAF 75/418 reads (18%) | called by muse, mutect2, varscan2
- TNR | c.141G>A p.E47= | Silent (SNP) | VAF 307/569 reads (54%) | catalogued as COSV54890441; called by muse, mutect2, varscan2
- TRIM46 | c.1488C>T p.P496= | Silent (SNP) | VAF 73/379 reads (19%) | catalogued as rs752842799; called by muse, mutect2, varscan2
- TRIM77 | c.822C>A p.T274= | Silent (SNP) | VAF 82/189 reads (43%) | called by muse, mutect2, varscan2
- TSNARE1 | c.606C>T p.L202= | Silent (SNP) | VAF 109/237 reads (46%) | catalogued as rs906256325, COSV56181957; called by muse, mutect2, varscan2
- UGT3A2 | c.897C>G p.T299= | Silent (SNP) | VAF 122/363 reads (34%) | called by muse, mutect2, varscan2
- VWF | c.6879G>C p.T2293= | Silent (SNP) | VAF 275/812 reads (34%) | catalogued as COSV54613252; called by muse, mutect2, varscan2
- WARS2 | c.765G>T p.V255= | Silent (SNP) | VAF 402/600 reads (67%) | called by muse, mutect2, varscan2
- WDR91 | c.1146G>T p.S382= | Silent (SNP) | VAF 166/382 reads (43%) | catalogued as COSV60369034; called by muse, mutect2, varscan2
- XKR6 | c.606G>T p.R202= | Silent (SNP) | VAF 144/206 reads (70%) | catalogued as rs757845278; called by muse, mutect2, varscan2
- YJU2 | c.156G>A p.K52= | Silent (SNP) | VAF 45/232 reads (19%) | catalogued as rs754654896; called by muse, mutect2, varscan2
- ZFC3H1 | c.519A>G p.R173= | Silent (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- ZNF280A | c.846A>G p.G282= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- ZNF841 | c.1818A>T p.T606= (on ENST00000426391 / NM_001369830.1; = p.T722= on NM_001136499.1 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- ZRANB3 | c.642C>A p.T214= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- ABCC3 | c.1636-30C>G | Intron (SNP) | VAF 52/139 reads (37%) | called by muse, mutect2, varscan2
- AC016582.1 | chr19:37824589 G>T | 3'Flank (SNP) | VAF 129/572 reads (23%) | called by muse, mutect2, varscan2
- AC100868.1 | c.152-2052T>C | Intron (SNP) | VAF 80/273 reads (29%) | catalogued as rs193023467; called by muse, mutect2, varscan2
- ADGB | c.4818+5515A>T | Intron (SNP) | VAF 118/410 reads (29%) | called by muse, mutect2, varscan2
- AL359195.2 | n.3621C>T | RNA (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- ALG12 | c.-38T>C | 5'UTR (SNP) | VAF 316/693 reads (46%) | catalogued as COSV100078034; called by muse, mutect2, varscan2
- ANXA2P2 | n.954C>T | RNA (SNP) | VAF 83/388 reads (21%) | catalogued as rs112536351; called by muse, varscan2
- BHLHE41 | c.*56del | 3'UTR (DEL) | VAF 55/348 reads (16%) | called by mutect2, pindel, varscan2
- BMERB1 | chr16:15591092 G>C | 3'Flank (SNP) | VAF 51/288 reads (18%) | called by muse, mutect2, varscan2
- BRD4 | c.2159-4478C>T | Intron (SNP) | VAF 27/142 reads (19%) | catalogued as rs547140283; called by muse, mutect2, varscan2
- C8B | c.-16C>G | 5'UTR (SNP) | VAF 250/369 reads (68%) | called by muse, mutect2, varscan2
- CCDC186 | c.-176C>T | 5'UTR (SNP) | VAF 108/204 reads (53%) | called by muse, mutect2, varscan2
- CYHR1 | c.246+177G>T | Intron (SNP) | VAF 145/792 reads (18%) | catalogued as rs143628277; called by muse, mutect2, varscan2
- DNM1 | c.1672-1656C>G | Intron (SNP) | VAF 41/149 reads (28%) | catalogued as rs1449464960; called by muse, mutect2, varscan2
- EARS2 | c.*2620G>T | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- EI24P4 | n.862C>A | RNA (SNP) | VAF 130/277 reads (47%) | called by muse, mutect2, varscan2
- FAM153CP | chr5:178055833 C>T | 3'Flank (SNP) | VAF 67/541 reads (12%) | called by muse, mutect2, varscan2
- FN1 | c.-9C>T | 5'UTR (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8435C>T | Intron (SNP) | VAF 140/252 reads (56%) | called by muse, mutect2, varscan2
- GCSH | chr16:81101275 C>A | 5'Flank (SNP) | VAF 40/136 reads (29%) | called by muse, mutect2
- GRM1 | c.-5C>A | 5'UTR (SNP) | VAF 228/561 reads (41%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1623G>A | RNA (SNP) | VAF 83/395 reads (21%) | catalogued as rs767203788; called by muse, mutect2, varscan2
- HMGN2P15 | n.20A>C | RNA (SNP) | VAF 24/694 reads (3%) | called by muse, mutect2
- KCND3 | chr1:111991137 C>G | 5'Flank (SNP) | VAF 65/98 reads (66%) | called by muse, mutect2, varscan2
- KIF6 | c.2428+339G>T | Intron (SNP) | VAF 14/284 reads (5%) | catalogued as rs1286815239; called by muse, mutect2
- KLF6 | c.*2635C>G | 3'UTR (SNP) | VAF 25/206 reads (12%) | called by muse, mutect2, varscan2
- LEKR1 | c.-4A>T | 5'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- MIR513B | n.69G>A | RNA (SNP) | VAF 101/163 reads (62%) | called by muse, mutect2, varscan2
- MRPS23 | c.-27A>T | 5'UTR (SNP) | VAF 77/411 reads (19%) | called by muse, mutect2, varscan2
- NDUFA11 | chr19:5903826 C>T | 5'Flank (SNP) | VAF 249/1046 reads (24%) | catalogued as rs1322571581; called by muse, mutect2, varscan2
- NDUFS2 | c.-18G>A | 5'UTR (SNP) | VAF 141/936 reads (15%) | catalogued as rs758249601; called by muse, mutect2, varscan2
- NLE1 | c.18+24G>C | Intron (SNP) | VAF 62/287 reads (22%) | called by muse, mutect2, varscan2
- NOL10 | c.1027-14775G>T | Intron (SNP) | VAF 65/261 reads (25%) | called by muse, mutect2, varscan2
- NOP56 | c.209-181C>A | Intron (SNP) | VAF 53/131 reads (40%) | catalogued as COSV61388804; called by muse, mutect2, varscan2
- OLAH | c.164-4809C>G | Intron (SNP) | VAF 77/434 reads (18%) | called by muse, mutect2, varscan2
- PLA2G15 | c.285-1481G>T | Intron (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*340G>A | 3'UTR (SNP) | VAF 15/510 reads (3%) | called by muse, mutect2
- PMPCB | c.99+159G>A | Intron (SNP) | VAF 234/437 reads (54%) | called by muse, mutect2, varscan2
- POMP | c.-55G>C | 5'UTR (SNP) | VAF 153/381 reads (40%) | called by muse, mutect2, varscan2
- PRCD | chr17:76544692 G>A | 3'Flank (SNP) | VAF 253/887 reads (29%) | called by muse, mutect2, varscan2
- RAD51D | c.*465C>G | 3'UTR (SNP) | VAF 56/367 reads (15%) | called by muse, mutect2, varscan2
- RBBP8NL | c.-3G>T | 5'UTR (SNP) | VAF 11/289 reads (4%) | called by muse, mutect2
- RETREG1 | c.-27C>A | 5'UTR (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2
- RNA5SP308 | chr10:28873273 C>A | 3'Flank (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- RNASET2 | c.262-36A>T | Intron (SNP) | VAF 75/185 reads (41%) | called by muse, mutect2, varscan2
- RTP2 | c.-383A>T | 5'UTR (SNP) | VAF 17/410 reads (4%) | called by muse, mutect2
- SYTL2 | c.1459+1601G>A | Intron (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.*18C>G | 3'UTR (SNP) | VAF 62/165 reads (38%) | called by muse, mutect2, varscan2
- TTC19 | c.*264C>A | 3'UTR (SNP) | VAF 103/149 reads (69%) | called by muse, mutect2, varscan2
- UBTFL2 | n.822C>A | RNA (SNP) | VAF 149/736 reads (20%) | catalogued as rs745972728; called by muse, mutect2, varscan2
- VSX1 | chr20:25071194 C>G | 3'Flank (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438654 T>A | 5'Flank (SNP) | VAF 22/648 reads (3%) | called by muse, mutect2
- ZIC2 | c.*333C>G | 3'UTR (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
